Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A71W, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A71W-01A (Primary Tumor).

Result Types: Surgical Pathology Report
Result Dates:
Performed By:
Encounter Info:

Surgical Pathology Report
MODIFIED-

Surgical Pathology Report

DIAGNOSIS:

A. Right kidney, radical nephrectomy: Papillary renal cell carcinoma (see synoptic report below).

Procedure/laterality: Right kidney, radical nephrectomy.
Histologic type: Papillary renal cell carcinoma.
Nuclear grade (Fuhrman 1-4): Larger lesion Fuhrman grade 2, smaller (0.8 cm) lesion Fuhrman grade 3.
Tumor size: 7 cm and 0.8 cm.
Tumor site: Lower pole (dominant tumor), smaller tumor in upper pole.
Tumor focality: Multifocal (two).
Sarcomatoid features: Not identified.
Tumor necrosis: Not identified.
Microscopic tumor extension:
Extension into perinephric tissue: Not identified.
Extension beyond Gerota's fascia: Not identified.
Extension into renal sinus: Not identified.
Extension into renal vein: Not identified.
Extension into collecting system: Not identified.
Extension into adrenal gland (if applicable): Not applicable.
Surgical margins: Negative for malignancy.
Lymph-vascular invasion: Not identified.
Lymph nodes: Not applicable.
Pathologic findings in non-neoplastic kidney: There is a 0.6-cm angiolipoma. The non-tumorous kidney shows no pathologic findings.
Pathologic staging: pT1b.
Biorepository sample (if applicable): Yes, contains carcinoma and benign kidney.
Block(s) containing malignancy suitable for additional testing: A3 through A5.
Additional pathologic findings/comment: There are two papillary renal cell carcinomas, 7.0 cm and 0.8 cm. These are papillary renal cell carcinoma type 1.

ADDITION:

The radical nephrectomy specimen is reexamined. Inspection confirms the absence of an adrenal gland in the resection specimen.

CLINICAL INFORMATION:

Renal mass.

SPECIMEN(S):
A. Right kidney

PRELIMINARY INTRAOPERATIVE DIAGNOSIS:

A. Right kidney frozen section diagnosis: Favor papillary renal cell carcinoma.

GROSS DESCRIPTION:

A. Received fresh labeled "right kidney."
Procedure: Radical nephrectomy.
Specimen laterality: Right.
Tumor site: The dominant tumor is located with the lower pole.
Tumor size: The dominant tumor measures 7.0 x 6.0 x 6.0 cm.
Tumor focality: Multifocal (see additional findings below).
Gross extent of dominant tumor:
Extension into perinephric tissue: Absent.
Extension beyond Gerota's fascia: Absent.
Extension into renal sinus: Absent.
Extension into renal vein: Not grossly identified.
Extension into collecting system: The mass grossly appears to abut the inferior calyx without gross involvement of the urothelium.
Additional Findings: There are two additional well-demarcated, tan-yellow lesions which measure 0.8 cm and 0.8 cm in greatest dimension. The smaller satellite lesion is located within the middle polar region toward posterior, and the larger lesion is located within the superior pole, toward anterior. The smaller lesion is located 2.0 cm superior of the mass, and the larger lesion is located 7.0 cm superior of the mass.
Adrenal gland: Absent.
Gross notes:
Gross tumor characteristics: The dominant tumor is hemorrhagic and focally tan-yellow to yellow-orange and well-demarcated. The two smaller satellite lesions have a tan-yellow and rubbery cut surface. The two smaller lesions are well-demarcated and grossly appear to be confined to the renal parenchyma without any gross involvement of the renal vein or renal pelvis, and are each located greater than 0.5 cm from the renal capsule.
Kidney weight: 692 g with fat, and 313 g without attached fat.
Kidney dimensions: 16.0 (superior to inferior) x 7.0 (medial to lateral) x 8.8 cm (anterior to posterior).
Ureter dimensions: Length 6.0 cm, and diameter 0.3 cm.
Lymph nodes: Absent.
Inking details: The outermost surface of the fat adjacent to the mass is inked blue.
Biorepository sample submitted: Yes, see block key.

Block key for specimen A:

A1) A representative section of the dominant mass submitted for frozen section; A2) vascular margins at hilum and ureter margins, shave; A3-A5) additional sections of mass in relation to outermost surface of kidney (presumed renal capsule); A6) mass in relation to inferior calyx; A7) mass in relation to adjacent parenchyma; A8) perpendicular sections from outermost surface of fat, in area closest to dominant mass; A9) mirror image of grossly normal parenchyma, as well as the dominant mass submitted for; A10) smaller lesion, closest to mass, entirely submitted; A11) larger lesion, furthest from dominant mass, entirely submitted; A12) parenchyma toward superior pole, away from mass and satellite superior calyx.

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were determined by

They have been determined by Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high complexity clinical laboratory testing.

ICD-O-3

Carcinoma, papillary renal cell
8260/3
Site B Kidney NOS
C64.9
JW 8/9/13

Criteria	JW 7/9/13	Yes	No
Prior Malignancy History	bank cell-skin	✓	✓

Source: NCI Genomic Data Commons file 96b9e18b-7309-4c8d-9c56-1ca665f96a0e (TCGA-SX-A71W.99290767-17D6-4EB6-AF0F-0231153F52AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).